CCDI case PBCFDU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4374fabf-4f69-49a6-9d1c-6be255f881ef

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.8 years (2,836 days).

Biospecimens (3 samples)
- Sample 0DR0C3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR0CC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR0CT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
